Somatic mutation profile of tumor specimen TCGA-BR-4368-01A (aliquot TCGA-BR-4368-01A-01D-1158-08) from TCGA case TCGA-BR-4368, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 78.8 years (28,770 days).
Specimen TCGA-BR-4368-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0ab433b-5574-4799-a5bd-ac7de8226958.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4368-11A (Solid Tissue Normal), aliquot TCGA-BR-4368-11A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/955ebe8c-063c-4b7e-b285-875f8dbd5e52

The open-access MAF lists 1,503 somatic variants for this specimen: 1,141 protein-altering or splice-affecting, 339 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 740, Silent 339, Frame Shift Del 289, Nonsense Mutation 46, Frame Shift Ins 32, Intron 18, Splice Site 12, Splice Region 12, In Frame Del 8, 5'Flank 2, In Frame Ins 1, RNA 1.

Variants (750 of 1,503; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as rs755747010, CM062415, COSV54059230; ClinVar: pathogenic; called by muse, mutect2
- ARID1B | c.4702C>T p.Q1568* | Nonsense Mutation (SNP) | VAF 91/294 reads (31%) | catalogued as rs1554235950, COSV51648505; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL10 | c.136del p.I46Yfs*24 | Frame Shift Del (DEL) | VAF 33/140 reads (24%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.5351dup p.N1784Kfs*3 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CPA1 | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782790983, CM139185, COSV50576310; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GAA | c.1942G>A p.G648S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536906561, CM980805, COSV56412369; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 45/155 reads (29%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 24/158 reads (15%) | catalogued as rs200923373, COSV70349021; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LDLR | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs773658037, CM011396, CM103826, CM981191, COSV52941747; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MOCS2 | c.65del p.P22Hfs*2 | Frame Shift Del (DEL) | VAF 11/94 reads (12%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | catalogued as rs760848629; ClinVar: pathogenic; called by pindel, varscan2
- PTPN11 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as rs121918467, CM043334, COSV61013465; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SETD5 | c.3855dup p.S1286Lfs*37 | Frame Shift Ins (INS) | VAF 40/132 reads (30%) | catalogued as rs1553641476; ClinVar: likely pathogenic; called by mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA2 | c.6014-1G>T p.X2005_splice (on ENST00000614293; = p.X1975_splice on NM_001606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 17/73 reads (23%) | catalogued as COSV55807128; called by muse, mutect2, varscan2
- ABCA5 | c.3234del p.F1078Lfs*6 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as COSV67016962; called by mutect2, pindel, varscan2
- ABCB4 | c.3074T>C p.L1025P | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.323); catalogued as COSV55942252; called by muse, mutect2, varscan2
- ABCC2 | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs149359610; ClinVar: uncertain significance; called by muse, mutect2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 27/54 reads (50%) | catalogued as rs749943218; called by mutect2, varscan2
- ABHD1 | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV53208372; called by muse, mutect2, varscan2
- ABTB1 | c.997G>A p.V333M (on ENST00000232744 / NM_172027.3; = p.V191M on NM_032548.3) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs770731601, COSV51743066; called by muse, mutect2, varscan2
- AC004922.1 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs767015647, COSV53559479; called by muse, mutect2, varscan2
- ACACA | c.6442C>T p.R2148* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as rs981281419; called by muse, mutect2, varscan2
- ACAD11 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV53901867; called by muse, mutect2, varscan2
- ACKR2 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56180501; called by muse, mutect2
- ACTN2 | c.1272G>T p.L424F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63978509; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 62/136 reads (46%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADA | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774510141, COSV100866542, COSV65739712; called by muse, mutect2, varscan2
- ADAD1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs375116122, COSV56647574; called by muse, mutect2, varscan2
- ADAM12 | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs369511795; called by muse, mutect2, varscan2
- ADAM30 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 94/514 reads (18%) | catalogued as COSV65562380; called by muse, mutect2, varscan2
- ADAMTS13 | c.3138G>T p.Q1046H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV63023289; called by muse, mutect2, varscan2
- ADAMTS14 | c.1522A>G p.S508G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV64606761; called by muse, mutect2, varscan2
- ADAMTS19 | c.2048A>G p.Y683C | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50802717; called by muse, mutect2, varscan2
- ADCY4 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53477624; called by muse, mutect2
- ADGRB2 | c.2156C>T p.T719I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57071535; called by muse, mutect2, varscan2
- ADGRE1 | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs542411645, COSV51678425; called by muse, mutect2, varscan2
- ADGRE1 | c.2639C>A p.P880Q | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV51681262, COSV99165338; called by muse, mutect2, varscan2
- ADGRL3 | c.2414G>A p.R805Q (on ENST00000506720 / NM_001322402.2; = p.R737Q on NM_015236.6) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs770571932, COSV72229230; called by muse, mutect2, varscan2
- ADRB2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60006329; called by muse, mutect2, varscan2
- AEBP1 | c.2549A>G p.K850R | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV56261510; called by muse, mutect2, varscan2
- AGTPBP1 | c.3280G>T p.G1094* (on ENST00000357081 / NM_001330701.2; = p.G1054* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 29/166 reads (17%) | catalogued as COSV61277814; called by muse, mutect2, varscan2
- AHCYL2 | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as rs759913689, COSV61491463; called by muse, mutect2, varscan2
- AHNAK2 | c.9749G>A p.G3250D | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60926635; called by muse, mutect2, varscan2
- AHR | c.2388G>T p.Q796H | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as COSV54126612; called by muse, mutect2, varscan2
- AKAP1 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756066356, COSV61807142; called by muse, mutect2, varscan2
- AL445524.2 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64150713; called by muse, mutect2, varscan2
- AL592490.1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV69425230, COSV69428005; called by muse, mutect2, varscan2
- ALDH1B1 | c.118T>C p.F40L | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs1466155836, COSV66620682; called by muse, mutect2, varscan2
- ALG10B | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 34/256 reads (13%) | catalogued as rs1397842268; called by mutect2, pindel, varscan2
- ALMS1 | c.3403G>A p.G1135S | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs1419651180, COSV52522684; called by muse, mutect2, varscan2
- AMBRA1 | c.1249T>G p.S417A (on ENST00000458649 / NM_001367468.1; = p.S327A on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV54063067; called by muse, mutect2
- ANAPC5 | c.1310T>C p.M437T | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55845572; called by muse, mutect2
- ANGPTL4 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs764172514, COSV56845682; called by muse, mutect2, varscan2
- ANKRD11 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 129/361 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56368549; called by muse, mutect2, varscan2
- ANKRD35 | c.2411G>A p.S804N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.959); catalogued as COSV62911682; called by muse, mutect2, varscan2
- ANKRD42 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1278396471, COSV52618643; called by muse, mutect2, varscan2
- ANLN | c.3185G>A p.R1062Q | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140729544, COSV56078104; called by muse, mutect2, varscan2
- ANO8 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752432408, COSV50184567; called by muse, mutect2, varscan2
- ANP32E | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV58483493; called by muse, mutect2, varscan2
- AOAH | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV51751081; called by muse, mutect2, varscan2
- AP002748.5 | c.986C>A p.P329H | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59147467; called by muse, mutect2, varscan2
- AP002748.5 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as rs748627604, COSV59151970; called by muse, mutect2, varscan2
- AP1S1 | c.23T>G p.F8C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61760962; called by muse, mutect2, varscan2
- AP3B2 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773489972, COSV55609201; called by muse, mutect2, varscan2
- APCDD1L | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.836); catalogued as COSV100954056, COSV64487960; called by muse, mutect2, varscan2
- APOL3 | c.718G>A p.V240M (on ENST00000349314 / NM_145640.2; = p.V169M on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs199785270, COSV62580897; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 64/209 reads (31%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP35 | c.662del p.K221Rfs*14 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | catalogued as rs1568467217; called by mutect2, pindel, varscan2
- ARHGEF2 | c.1712G>A p.R571H (on ENST00000361247 / NM_001162383.2; = p.R543H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.876); catalogued as rs544890242, COSV58117647; called by muse, mutect2, varscan2
- ARHGEF7 | c.1676C>T p.S559L (on ENST00000375741 / NM_001113511.2; = p.S381L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.096); catalogued as rs755073581, COSV54552201; called by muse, mutect2, varscan2
- ARID1A | c.1416_1417insA p.Q473Tfs*150 | Frame Shift Ins (INS) | VAF 97/483 reads (20%) | catalogued as COSV100250010; called by mutect2, pindel, varscan2
- ARL16 | c.255del p.C86Afs*19 | Frame Shift Del (DEL) | VAF 32/252 reads (13%) | catalogued as rs752241785; called by mutect2, pindel, varscan2
- ARMCX5-GPRASP2 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63439163; called by muse, mutect2, varscan2
- ARMH3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as COSV60752383; called by muse, mutect2, varscan2
- ARR3 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV57205479; called by muse, mutect2, varscan2
- ARSF | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 33/146 reads (23%) | catalogued as rs199811641, COSV100839500, COSV63839423; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs753865255; called by mutect2, varscan2
- AS3MT | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV54919210; called by muse, mutect2, varscan2
- ASAP1 | c.3103G>A p.A1035T | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1320023827, COSV63054829; called by muse, mutect2, varscan2
- ASAP1 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63054834; called by muse, mutect2, varscan2
- ASAP2 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV55637770; called by muse, mutect2, varscan2
- ASCC3 | c.5066G>A p.R1689H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762041515, COSV64981525; called by muse, mutect2, varscan2
- ASH2L | c.1478C>A p.P493H | Missense Mutation (SNP) | VAF 121/645 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51701912; called by muse, mutect2, varscan2
- ASIC4 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750769790, COSV61732835; called by muse, mutect2, varscan2
- ASXL1 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.121); catalogued as COSV60123075; called by muse, mutect2, varscan2
- ASXL2 | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV55453686, COSV55468449; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 48/168 reads (29%) | catalogued as rs746676748; called by mutect2, varscan2
- ATG2A | c.4061G>A p.G1354E | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV65968984; called by muse, mutect2, varscan2
- ATP10A | c.4276del p.L1426Cfs*66 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | catalogued as rs768534594; called by mutect2, pindel, varscan2
- ATP2B3 | c.3565G>A p.G1189S | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.901); catalogued as rs782466704, COSV54861939; called by muse, mutect2, varscan2
- ATP8B4 | c.964T>C p.S322P | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52725064; called by muse, mutect2, varscan2
- ATPSCKMT | c.113T>C p.F38S | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV54727821; called by muse, mutect2, varscan2
- ATRX | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV64884094; called by muse, mutect2, varscan2
- ATXN7 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 142/359 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.238); catalogued as COSV55756971; called by muse, mutect2, varscan2
- AURKC | c.893G>A p.R298Q (on ENST00000302804 / NM_001015878.2; = p.R264Q on NM_003160.3) | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs575228273, COSV57140463; called by muse, mutect2, varscan2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs770737105, COSV57327371; called by mutect2, pindel, varscan2
- BACH1 | c.1745T>C p.I582T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54521331; called by muse, mutect2
- BAZ1B | c.4087C>T p.P1363S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59994827; called by muse, mutect2, varscan2
- BAZ2A | c.5048G>A p.R1683Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs201216445, COSV51644321; called by mutect2, varscan2
- BCAN | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as COSV61259816; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV63247508; called by muse, mutect2, varscan2
- BLZF1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs779528195, COSV61394981; called by muse, mutect2, varscan2
- BMP1 | c.1469A>G p.Y490C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60484162; called by muse, mutect2, varscan2
- BMP5 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs757210060, COSV63706779; called by muse, mutect2, varscan2
- BMPR1B | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52777946, COSV52782132; called by muse, mutect2, varscan2
- BNC2 | c.1380C>A p.Y460* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as COSV66158094; called by muse, mutect2, varscan2
- BPTF | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV58847774; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs763134487; called by mutect2, varscan2
- BSN | c.6709C>T p.P2237S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99606968; called by muse, mutect2
- BSN | c.7513dup p.L2505Pfs*13 | Frame Shift Ins (INS) | VAF 11/68 reads (16%) | catalogued as rs754418611; called by mutect2, varscan2
- BTK | c.482del p.N161Mfs*15 | Frame Shift Del (DEL) | VAF 52/253 reads (21%) | catalogued as COSV58124489; called by mutect2, pindel, varscan2
- BTN2A1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1404295878, COSV57001966; called by muse, mutect2
- C11orf80 | c.1580G>A p.S527N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV58994594; called by muse, mutect2, varscan2
- C14orf28 | c.425dup p.N142Kfs*3 | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | catalogued as rs566011631; called by mutect2, pindel, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | catalogued as COSV62298237; called by mutect2, varscan2
- C4B | c.3872G>A p.R1291H | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs776621861, COSV70313795; called by muse, mutect2, varscan2
- C6orf47 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV63264205; called by muse, mutect2, varscan2
- CACNA1B | c.1859T>C p.I620T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV53150354; called by muse, mutect2, varscan2
- CACNA1C | c.5941C>T p.R1981* (on ENST00000399634 / NM_001167625.1; = p.R1910* on NM_000719.7) | Nonsense Mutation (SNP) | VAF 35/168 reads (21%) | catalogued as rs1556291640, COSV59741294, COSV59776352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV55465989; called by muse, mutect2, varscan2
- CACTIN | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV50273849; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN3 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 37/160 reads (23%) | catalogued as COSV58826688; called by muse, mutect2, varscan2
- CARD11 | c.2140C>T p.L714= | Splice Region (SNP) | VAF 22/80 reads (28%) | catalogued as COSV62757230; called by muse, mutect2, varscan2
- CARTPT | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV57115894; called by muse, mutect2, varscan2
- CATSPER4 | c.1401del p.K467Nfs*78 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs769908264; called by mutect2, varscan2
- CATSPERE | c.2372A>T p.D791V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV63682391; called by muse, mutect2, varscan2
- CAVIN4 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.367); catalogued as rs775051470, COSV56868460; called by muse, mutect2, varscan2
- CBL | c.2291C>A p.P764H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV50663874, COSV50666669; called by muse, mutect2, varscan2
- CBLN2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs1281951081, COSV54050115; called by muse, mutect2, varscan2
- CBWD1 | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV58703161; called by mutect2, varscan2
- CCDC170 | c.1914del p.K638Nfs*24 | Frame Shift Del (DEL) | VAF 33/226 reads (15%) | catalogued as rs751612825; called by mutect2, pindel, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 32/154 reads (21%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC38 | c.329A>G p.H110R | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs764095478, COSV60185170; called by muse, mutect2, varscan2
- CCDC62 | c.1741G>T p.G581C | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV53437276; called by muse, mutect2, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs781790231; called by mutect2, varscan2
- CD44 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369496409; called by muse, mutect2, varscan2
- CD70 | c.233del p.G78Afs*33 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as COSV99835502; called by mutect2, pindel
- CD81 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs374100694, COSV55132282; called by muse, mutect2, varscan2
- CD81 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV55134202; called by muse, mutect2, varscan2
- CDC26 | c.125G>T p.S42I | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.798); catalogued as COSV65262122; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 34/162 reads (21%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH6 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs370500416; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs746203438, COSV62573211, COSV62573947; called by muse, mutect2, varscan2
- CDK6 | c.460A>T p.T154S | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.289); catalogued as COSV56013909; called by muse, mutect2, varscan2
- CDKL4 | c.102del p.K34Nfs*14 | Frame Shift Del (DEL) | VAF 34/147 reads (23%) | catalogued as rs1278195821; called by mutect2, pindel, varscan2
- CDON | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.37); catalogued as rs761054118, COSV54995637; ClinVar: likely benign; called by muse, mutect2
- CDX2 | c.916dup p.V306Gfs*31 | Frame Shift Ins (INS) | VAF 13/71 reads (18%) | catalogued as rs773511514; called by mutect2, varscan2
- CELF2 | c.802G>A p.G268S (on ENST00000416382 / NM_001025077.3; = p.G275S on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs573495632, COSV59980428; called by muse, mutect2, varscan2
- CELSR2 | c.5137G>A p.G1713S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.265); catalogued as rs752581225, COSV54779822; called by mutect2, varscan2
- CENPF | c.6038C>T p.T2013M | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as rs150986314; called by muse, mutect2, varscan2
- CENPJ | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV67884319; called by muse, mutect2, varscan2
- CEP126 | c.2107G>T p.G703* | Nonsense Mutation (SNP) | VAF 12/250 reads (5%) | catalogued as COSV54831058; called by muse, mutect2
- CES4A | c.848A>T p.N283I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV58658340; called by muse, mutect2, varscan2
- CETN3 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51618340; called by muse, mutect2, varscan2
- CFAP299 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs528646259, COSV63881985; called by muse, mutect2, varscan2
- CH25H | c.30G>T p.Q10H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV64092579; called by muse, mutect2, varscan2
- CHCHD3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs774870383, COSV52769517; called by muse, mutect2
- CHL1 | c.3502G>A p.G1168R (on ENST00000397491 / NM_001253387.1; = p.G1184R on NM_006614.4) | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200848343, COSV56585358; called by muse, mutect2, varscan2
- CHML | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as COSV59367611; called by muse, mutect2, varscan2
- CHPF2 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV50401271; called by muse, mutect2, varscan2
- CHRNA6 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753856041, COSV52381153; called by muse, mutect2, varscan2
- CHRNA9 | c.117del p.F39Lfs*18 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | catalogued as rs1162213951; called by mutect2, pindel, varscan2
- CIC | c.3743del p.P1248Hfs*54 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV50671496; called by mutect2, varscan2
- CILP | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV56022354; called by muse, mutect2, varscan2
- CLC | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV55686563; called by muse, mutect2, varscan2
- CLDN15 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV56192145; called by muse, mutect2
- CLPS | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs755023217, COSV52566762; called by muse, mutect2, varscan2
- CLSTN1 | c.1844C>T p.T615M (on ENST00000377298 / NM_001009566.3; = p.T605M on NM_014944.4) | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424803630, COSV63647855; called by muse, mutect2, varscan2
- CLSTN1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1257860388, COSV63651326; called by muse, mutect2, varscan2
- CLUH | c.1324del p.D442Tfs*12 (on ENST00000435359; = p.D480Tfs*12 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs752224729; called by mutect2, pindel, varscan2
- CMTR2 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs148258352; called by muse, varscan2
- CNGA2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs375875187, COSV61706410; called by muse, mutect2, varscan2
- CNTN6 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1472431781, COSV63190823; called by muse, mutect2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs374805044; called by mutect2, varscan2
- COG5 | c.2104A>G p.R702G (on ENST00000347053 / NM_001379512.1; = p.R723G on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51765354; called by muse, mutect2
- COG7 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV56153412; called by muse, mutect2, varscan2
- COL12A1 | c.866C>A p.S289Y | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59408886; called by muse, mutect2, varscan2
- COL15A1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV100897305, COSV100897519; called by muse, mutect2
- COL21A1 | c.1931G>A p.G644D | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55181261, COSV99779484; called by muse, mutect2, varscan2
- COL6A2 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906608, CM050226, COSV52426386; ClinVar: uncertain significance; called by mutect2, varscan2
- COL7A1 | c.7964C>T p.A2655V | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs761910447, COSV56477341; called by muse, mutect2
- COLGALT2 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV62300792; called by muse, mutect2, varscan2
- CORO1C | c.1390A>G p.K464E | Missense Mutation (SNP) | VAF 100/300 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV54599140; called by muse, mutect2, varscan2
- CPA1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs537076438, COSV50576261; called by muse, mutect2, varscan2
- CPA4 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55983237; called by muse, mutect2
- CPN1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752224544, COSV64941882; called by muse, mutect2, varscan2
- CPN2 | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV60472102; called by muse, mutect2, varscan2
- CPSF1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as rs1554865314, COSV62942538; called by muse, mutect2, varscan2
- CPZ | c.326G>A p.C109Y (on ENST00000360986 / NM_001014447.3; = p.C98Y on NM_003652.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59926332; called by muse, mutect2, varscan2
- CRABP2 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 31/106 reads (29%) | catalogued as rs750232968, COSV63958824, COSV63959181; called by muse, mutect2, varscan2
- CRACDL | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs775019973, COSV67407590, COSV67409395, COSV67410310; called by muse, mutect2, varscan2
- CREBBP | c.7150del p.H2384Tfs*12 | Frame Shift Del (DEL) | VAF 49/205 reads (24%) | catalogued as COSV52136889; called by mutect2, pindel, varscan2
- CRIP1 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV57636244; called by mutect2, varscan2
- CRTAC1 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54010410; called by muse, mutect2, varscan2
- CRYBB1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs754411906, COSV53232510; called by muse, mutect2, varscan2
- CSHL1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 66/331 reads (20%) | catalogued as COSV51990407; called by muse, mutect2, varscan2
- CSMD1 | c.10685G>T p.C3562F (on ENST00000520002; = p.C3561F on NM_033225.6) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59358522; called by muse, mutect2, varscan2
- CSMD1 | c.8134C>T p.R2712W (on ENST00000520002; = p.R2711W on NM_033225.6) | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs562712934, COSV59388350; called by muse, mutect2, varscan2
- CSMD1 | c.3282G>T p.W1094C (on ENST00000520002; = p.W1093C on NM_033225.6) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59388375; called by muse, mutect2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs766438669; called by mutect2, varscan2
- CSNK1G2 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs893822808, COSV55337303; called by muse, mutect2, varscan2
- CTPS2 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63724463; called by muse, varscan2
- CUBN | c.5903G>A p.G1968D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs778249964, COSV64716019; called by muse, mutect2, varscan2
- CUL9 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs775004799, COSV52735213; called by muse, mutect2, varscan2
- CUX2 | c.2672A>G p.Y891C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs1199798273, COSV55648858; called by muse, mutect2, varscan2
- CUZD1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); catalogued as COSV59028257; called by muse, mutect2, varscan2
- CYB5R1 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273317219, COSV65917381; called by muse, mutect2, varscan2
- CYFIP1 | c.3263G>A p.C1088Y | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV57416870; called by muse, mutect2, varscan2
- CYP2D6 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.909); catalogued as rs77578877, COSV100637225; called by muse, mutect2
- CYP4B1 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54721596; called by muse, mutect2, varscan2
- CYP8B1 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs528095572, COSV60225829; called by muse, mutect2, varscan2
- CYTH3 | c.833G>A p.R278H (on ENST00000396741; = p.R277H on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs750874462, COSV60358860; called by muse, mutect2, varscan2
- DAAM2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs1265056284, COSV51368291; called by muse, mutect2, varscan2
- DAAM2 | c.2114A>T p.Q705L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV51420701; called by muse, mutect2, varscan2
- DAND5 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as COSV57684660; called by muse, mutect2, varscan2
- DBR1 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV53431286; called by muse, varscan2
- DCAF11 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58109096; called by muse, mutect2, varscan2
- DCAF12L2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.271); catalogued as COSV63580171; called by muse, mutect2, varscan2
- DCAF4 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62320607; called by muse, mutect2, varscan2
- DCAF5 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs770821356, COSV58460269; called by muse, mutect2, varscan2
- DCAF8L1 | c.827G>A p.C276Y | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV71595545; called by muse, mutect2, varscan2
- DCAF8L1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as rs757067588, COSV71595546; called by muse, mutect2, varscan2
- DCSTAMP | c.244A>T p.I82F | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as COSV52579459, COSV52580294; called by muse, mutect2, varscan2
- DDAH2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65383645; called by muse, mutect2, varscan2
- DDX18 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs748867652, COSV54309342; called by muse, mutect2, varscan2
- DDX19A | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100156100; called by muse, mutect2, varscan2
- DDX19B | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV55366392; called by muse, varscan2
- DDX50 | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as rs748915927, COSV65293433; called by muse, mutect2, varscan2
- DECR1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.018); catalogued as COSV55170846, COSV55170914; called by muse, mutect2
- DENND2D | c.1405dup p.T469Nfs*13 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | catalogued as rs765960547; called by mutect2, pindel, varscan2
- DENND4B | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1480937743, COSV63412130; called by muse, mutect2, varscan2
- DHX30 | c.3098G>A p.G1033D (on ENST00000445061 / NM_138615.3; = p.G994D on NM_014966.3) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV53143008; called by muse, mutect2, varscan2
- DIDO1 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs138811075; called by muse, mutect2
- DIP2B | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.253); catalogued as rs1369286164, COSV56592688; called by muse, mutect2, varscan2
- DISP3 | c.2974G>A p.V992M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs371132450, COSV53830324; called by muse, mutect2, varscan2
- DLGAP1 | c.654del p.S219Rfs*3 | Frame Shift Del (DEL) | VAF 49/257 reads (19%) | catalogued as rs1568274560; called by mutect2, pindel, varscan2
- DLGAP4 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as rs575670266, COSV59414947; called by muse, mutect2, varscan2
- DNAH11 | c.2832del p.Q945Kfs*4 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as COSV60968530; called by mutect2, pindel, varscan2
- DNAH2 | c.1604C>A p.P535Q | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV50021238; called by muse, mutect2, varscan2
- DNAH5 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs755574532, COSV54233163; called by muse, mutect2, varscan2
- DNAH7 | c.8254C>T p.L2752F | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747984547, COSV56788306; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAH8 | c.11875G>T p.G3959C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344978723, COSV59482770; called by muse, mutect2, varscan2
- DNAH9 | c.10184A>G p.K3395R | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as COSV52378345; called by muse, mutect2, varscan2
- DNAJC13 | c.4998del p.G1667Vfs*22 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as COSV53444955; called by mutect2, pindel
- DNAJC7 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57270522; called by muse, mutect2, varscan2
- DOCK3 | c.4754T>G p.L1585R | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56551410; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 14/108 reads (13%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOHH | c.151T>C p.S51P | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51746179; called by muse, mutect2, varscan2
- DOP1A | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52718698; called by muse, mutect2, varscan2
- DOP1B | c.224T>A p.L75Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54281785; called by muse, mutect2, varscan2
- DPF3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757444001, COSV63503378; called by muse, mutect2, varscan2
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs748560644; called by mutect2, pindel
- DPP8 | c.2671C>T p.R891C (on ENST00000341861 / NM_001320875.2; = p.R775C on NM_017743.6) | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV55683561; called by muse, mutect2, varscan2
- DPPA4 | c.600G>T p.E200D | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV59512604; called by muse, mutect2, varscan2
- DPYD | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs573299212, COSV64615892; called by muse, mutect2, varscan2
- DPYSL3 | c.690+1G>A p.X230_splice | Splice Site (SNP) | VAF 24/108 reads (22%) | catalogued as COSV58331411; called by muse, mutect2, varscan2
- DSC3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs137869359; called by muse, mutect2, varscan2
- DSCAM | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.202); catalogued as COSV68030288; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs750962255; called by mutect2, varscan2
- DUOX1 | c.4010G>A p.R1337Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779696519, COSV58486752; called by muse, mutect2, varscan2
- DUS2 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV62709948; called by muse, mutect2, varscan2
- DUS3L | c.1454G>T p.C485F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57833763; called by muse, mutect2, varscan2
- DUSP22 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs140673019, COSV60531870; called by muse, mutect2
- DYNC1H1 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64143104; called by muse, mutect2, varscan2
- DYNC1LI2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762198514, COSV50754090; called by muse, mutect2, varscan2
- E2F7 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59743756; called by muse, mutect2, varscan2
- EBF1 | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58196183; called by muse, mutect2, varscan2
- EBF2 | c.1562G>A p.S521N | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); catalogued as COSV68780736; called by muse, mutect2, varscan2
- ECEL1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs369255583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDAR | c.804C>T p.S268= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as rs143674939; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs367598001; called by muse, varscan2
- EGR4 | c.1412C>T p.T471M (on ENST00000545030; = p.T368M on NM_001965.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV71532331; called by muse, mutect2, varscan2
- EIF1AX | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV63309487; called by muse, mutect2, varscan2
- EIF2B3 | c.347A>C p.E116A | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV64518848; called by muse, varscan2
- EIF4E1B | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765322594, COSV53782101; called by muse, mutect2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs751148694; called by mutect2, varscan2
- EP400 | c.8252C>T p.T2751M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.897); catalogued as rs531098130, COSV57778942; called by muse, mutect2, varscan2
- EPB41 | c.877C>T p.P293S (on ENST00000343067 / NM_001166005.2; = p.P84S on NM_004437.4) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58054721; called by muse, mutect2, varscan2
- EPB41L3 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs143942399; called by muse, mutect2
- EPB41L4A | c.885del p.F295Lfs*35 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs1157347372; called by mutect2, pindel
- EPOR | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55801669; called by muse, mutect2, varscan2
- EPPK1 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as COSV73262414; called by muse, mutect2
- EPPK1 | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782407539, COSV101599710; called by muse, mutect2, varscan2
- EPS8L1 | c.1097C>T p.A366V (on ENST00000201647 / NM_133180.3; = p.A239V on NM_017729.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV52386577; called by muse, mutect2
- ERBIN | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52327589; called by muse, mutect2, varscan2
- FAAH2 | c.98del p.G33Vfs*12 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | catalogued as COSV100887477; called by mutect2, pindel, varscan2
- FADS1 | c.795del p.A266Pfs*60 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | catalogued as COSV63520643; called by mutect2, pindel, varscan2
- FAM135B | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773803774, COSV52755186; called by mutect2, varscan2
- FAM184A | c.2509C>T p.R837W | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs772310108, COSV58858215, COSV58859076; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM222B | c.864T>A p.C288* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV57934450; called by muse, mutect2, varscan2
- FAM43A | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs867924850, COSV61673588; called by mutect2, varscan2
- FAM71B | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs146575394; called by muse, mutect2, varscan2
- FAM71F1 | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59375025; called by muse, mutect2, varscan2
- FAM91A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760648737, COSV58235570; called by muse, mutect2, varscan2
- FAM9A | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); catalogued as COSV66813783; called by muse, mutect2, varscan2
- FAN1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | catalogued as rs766068447, COSV62952234; called by muse, mutect2, varscan2
- FASTKD3 | c.428del p.K143Rfs*36 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs773607911, COSV52947201; called by mutect2, pindel, varscan2
- FAT2 | c.4274G>A p.G1425E | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55830097; called by muse, mutect2, varscan2
- FAT3 | c.12086C>T p.P4029L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs1473992762, COSV53178255; called by muse, mutect2, varscan2
- FBLN1 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 106/514 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs760646592, COSV59942899; called by muse, varscan2
- FBXO3 | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55768212; called by muse, mutect2, varscan2
- FBXW10 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.118); catalogued as COSV57322704; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FGD3 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.212); catalogued as COSV100490317; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FHOD3 | c.3997G>A p.V1333I (on ENST00000359247 / NM_001281739.3; = p.V1350I on NM_025135.5) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs149906669; called by muse, mutect2, varscan2
- FICD | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs372450332; called by muse, mutect2, varscan2
- FLG2 | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.333); catalogued as COSV66173767; called by muse, mutect2, varscan2
- FLRT3 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs142379846; called by muse, mutect2, varscan2
- FNDC3A | c.389C>T p.P130L (on ENST00000492622 / NM_001079673.2; = p.P74L on NM_014923.5) | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs765409328, COSV65697155; called by muse, mutect2, varscan2
- FOXP4 | c.1117C>T p.R373W (on ENST00000307972 / NM_001012426.1; = p.R372W on NM_138457.3) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs140387832; called by muse, mutect2
- FSCN3 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.081); catalogued as rs376914564, COSV50000121; called by muse, mutect2, varscan2
- FUCA2 | c.559T>C p.F187L | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV50021157; called by muse, mutect2, varscan2
- FUNDC2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100811216; called by muse, mutect2, varscan2
- GBP5 | c.394A>G p.N132D | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV58594451; called by muse, mutect2, varscan2
- GCM1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV52524150; called by muse, mutect2, varscan2
- GFRA2 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV60779152; called by muse, mutect2, varscan2
- GLDC | c.2392G>T p.G798* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as COSV58685557; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 89/348 reads (26%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI2 | c.2072C>T p.A691V (on ENST00000361492 / NM_001374353.1; = p.A708V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.035); catalogued as COSV58052009; called by mutect2, varscan2
- GLRA4 | c.494+2T>C p.X165_splice | Splice Site (SNP) | VAF 69/396 reads (17%) | catalogued as COSV65457051; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 19/134 reads (14%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNL2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV66081142; called by muse, mutect2, varscan2
- GNL3L | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs148611493, COSV60577759; called by muse, varscan2
- GNPTG | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50190874; called by muse, mutect2, varscan2
- GOLGA3 | c.1317G>T p.Q439H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV52644451; called by muse, mutect2, varscan2
- GOLGA3 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 110/615 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.231); catalogued as COSV52629827; called by muse, mutect2, varscan2
- GOLM1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748551343, COSV57415891; called by muse, mutect2, varscan2
- GPR146 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52467327; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 48/232 reads (21%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR75 | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs201187126, COSV61832654; called by muse, mutect2, varscan2
- GPRC5B | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753216789, COSV56028889; called by muse, mutect2, varscan2
- GPRC5C | c.1068C>A p.S356R (on ENST00000652232; = p.S311R on NM_018653.4) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as COSV61239051; called by muse, mutect2, varscan2
- GRAMD2B | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53510390; called by muse, mutect2, varscan2
- GRB7 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.384); catalogued as rs751537147, COSV58448595; called by mutect2, varscan2
- GREB1 | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52197051; called by muse, mutect2, varscan2
- GRIA2 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs766785821, COSV52407218; called by muse, mutect2
- GRID2 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772260836, COSV56271597; called by muse, mutect2, varscan2
- GRIN3A | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV62454331; called by muse, mutect2, varscan2
- GRK3 | c.1844A>T p.K615I | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60800704; called by muse, mutect2, varscan2
- GRM1 | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51364485; called by muse, mutect2, varscan2
- GTF2I | c.566del p.L189* | Frame Shift Del (DEL) | VAF 93/342 reads (27%) | catalogued as COSV60399209; called by mutect2, pindel, varscan2
- GTF3C1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.308); catalogued as rs746419913, COSV55192602; called by muse, mutect2, varscan2
- H4C9 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV62890281; called by muse, mutect2, varscan2
- HABP2 | c.1252A>C p.K418Q | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV63494184; called by muse, mutect2, varscan2
- HADHB | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV58548767; called by muse, mutect2
- HECTD3 | c.1268A>G p.H423R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV55802077; called by muse, mutect2, varscan2
- HEXA | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs373781108, COSV51509032; called by muse, mutect2, varscan2
- HHAT | c.1047T>G p.Y349* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV54810696; called by muse, mutect2
- HIRA | c.2980A>G p.I994V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV54280183; called by muse, mutect2, varscan2
- HIRA | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54280197, COSV99600323; called by muse, mutect2, varscan2
- HJV | c.914C>T p.A305V (on ENST00000336751 / NM_213653.4; = p.A192V on NM_145277.5) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.1); catalogued as COSV60953248; called by muse, mutect2
- HMCN1 | c.3847C>T p.R1283C | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs781327521, COSV54944264; called by muse, mutect2, varscan2
- HMCN1 | c.13516G>T p.E4506* | Nonsense Mutation (SNP) | VAF 38/177 reads (21%) | catalogued as COSV54944279; called by muse, mutect2, varscan2
- HMMR | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV62375559; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPH3 | c.394A>G p.M132V | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV56263419; called by muse, mutect2, varscan2
- HNRNPR | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV56424468; called by muse, mutect2, varscan2
- HNRNPUL1 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 65/358 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as COSV54567194; called by muse, mutect2, varscan2
- HSDL1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54742330; called by muse, mutect2
- HTR1B | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.182); catalogued as rs774927649, COSV64051983; called by muse, mutect2, varscan2
- HTRA1 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as rs754158219, COSV64564263; called by muse, mutect2, varscan2
- HUWE1 | c.7808G>A p.R2603Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); catalogued as rs146149373, COSV53345431; called by muse, mutect2, varscan2
- HUWE1 | c.7081G>A p.G2361R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs1556943291, COSV53351450; called by muse, mutect2, varscan2
- ICAM1 | c.19del p.R7Gfs*40 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as COSV53423883; called by mutect2, pindel, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs759151580; called by pindel, varscan2
- IFNAR1 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV54254525; called by muse, mutect2, varscan2
- IFNAR1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332193148, COSV54254538; called by muse, varscan2
- IGF2BP1 | c.909G>T p.E303D | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); catalogued as COSV51736391; called by muse, mutect2, varscan2
- IGHV3-74 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as rs557378029; called by muse, mutect2, varscan2
- IGSF1 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); catalogued as rs149790689, COSV63837202; called by muse, mutect2, varscan2
- IGSF10 | c.5266A>G p.T1756A | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56792166; called by muse, mutect2, varscan2
- IKZF3 | c.516A>C p.K172N | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53105248; called by muse, varscan2
- IL1RL2 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51819322; called by muse, mutect2, varscan2
- IL2RG | c.359del p.K120Rfs*27 | Frame Shift Del (DEL) | VAF 21/154 reads (14%) | catalogued as CD159812; called by mutect2, pindel, varscan2
- ING1 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV58172186; called by muse, mutect2, varscan2
- INHA | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs758448367, COSV54715676, COSV54721562; called by muse, mutect2, varscan2
- INHBA | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV99636980; called by muse, mutect2, varscan2
- INHBB | c.949T>C p.W317R | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54679287; called by muse, mutect2, varscan2
- INPPL1 | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.297); catalogued as rs750607140, COSV53359616; called by muse, mutect2, varscan2
- INTS12 | c.41del p.L14* | Frame Shift Del (DEL) | VAF 42/239 reads (18%) | catalogued as COSV60863912; called by mutect2, pindel, varscan2
- INTS8 | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752848840, COSV57377601; called by muse, mutect2, varscan2
- INVS | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs550039026, COSV52438850; called by muse, mutect2
- IPO5 | c.2873C>T p.A958V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1324017361, COSV55157115; called by muse, mutect2, varscan2
- IRF2 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66928684, COSV66929319; called by muse, mutect2
- IRX1 | c.696G>C p.K232N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV57362647; called by muse, mutect2, varscan2
- ITGA9 | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV53253543; called by muse, mutect2, varscan2
- ITGAV | c.3104A>G p.Q1035R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53719360; called by muse, mutect2, varscan2
- ITGBL1 | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV66012279; called by muse, mutect2, varscan2
- ITSN2 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs200633067, COSV61954269; called by muse, varscan2
- IVD | c.262G>A p.G88R (on ENST00000651168; = p.G85R on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51101719; called by muse, varscan2
- JAK2 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs373174105, COSV67590955; called by muse, mutect2, varscan2
- JMJD1C | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV67867949; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV59828651; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV59827402, COSV59828667; called by muse, mutect2, varscan2
- JPH4 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV62509712; called by muse, mutect2, varscan2
- KBTBD4 | c.1156dup p.E386Gfs*4 | Frame Shift Ins (INS) | VAF 27/179 reads (15%) | catalogued as rs756343868, COSV58597480; called by mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNG1 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.521); catalogued as COSV65370544; called by muse, mutect2
- KCNH1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV55105876; called by muse, varscan2
- KCNH5 | c.2890del p.Q964Rfs*59 | Frame Shift Del (DEL) | VAF 54/246 reads (22%) | catalogued as COSV59763617; called by mutect2, varscan2
- KCNJ14 | c.223A>C p.S75R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as COSV53520935; called by muse, varscan2
- KCNQ3 | c.1828A>G p.T610A | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV66482757; called by muse, mutect2, varscan2
- KCTD15 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52292144; called by muse, mutect2, varscan2
- KCTD21 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs772092002, COSV60740677; called by muse, mutect2, varscan2
- KDM4B | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50267843; called by muse, mutect2, varscan2
- KDM4C | c.2253G>C p.W751C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV67193371; called by muse, mutect2, varscan2
- KEL | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs199509304, COSV62336463; called by muse, mutect2
- KIAA0100 | c.3264G>A p.S1088= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as rs1298092333, COSV66491283; called by muse, mutect2, varscan2
- KIAA1109 | c.4770del p.K1590Nfs*11 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | catalogued as rs779140281, COSV52689741; called by mutect2, varscan2
- KIF3C | c.1666A>T p.M556L | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53101992; called by muse, varscan2
- KLHDC3 | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.196); catalogued as COSV55065633, COSV55065807; called by muse, mutect2, varscan2
- KLHDC7B | c.1385G>A p.R462H (on ENST00000395676; = p.R1103H on NM_138433.5) | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758694348, COSV67465283; called by muse, mutect2, varscan2
- KLHL25 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV61995427; called by muse, mutect2
- KLHL8 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56749781; called by muse, mutect2, varscan2
- KMT2D | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV56489688; called by muse, mutect2
- KNG1 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53980349, COSV53981268; called by muse, mutect2, varscan2
- KNL1 | c.596dup p.S200Vfs*12 (on ENST00000346991 / NM_170589.5; = p.S174Vfs*12 on NM_144508.5) | Frame Shift Ins (INS) | VAF 16/94 reads (17%) | catalogued as rs1280196367; called by mutect2, pindel, varscan2
- KNL1 | c.3170C>T p.A1057V (on ENST00000346991 / NM_170589.5; = p.A1031V on NM_144508.5) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV61160733; called by muse, mutect2, varscan2
- KRT31 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV52438874; called by muse, mutect2, varscan2
- KRT6B | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as rs150021015, COSV52886797; called by muse, mutect2, varscan2
- KRT7 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs771955592, COSV59333225; called by muse, mutect2, varscan2
- KRT82 | c.777G>A p.E259= | Splice Region (SNP) | VAF 28/103 reads (27%) | catalogued as COSV57787357; called by muse, mutect2, varscan2
- LALBA | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56396598; called by muse, mutect2, varscan2
- LAMB3 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs754855375, COSV61920002; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 28/162 reads (17%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARS2 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 123/350 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1306681916, COSV55532425; called by muse, mutect2, varscan2
- LAS1L | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867338874, COSV56709175; called by muse, mutect2, varscan2
- LATS2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.073); catalogued as COSV66874036; called by muse, mutect2
- LAYN | c.875A>G p.Y292C (on ENST00000375615 / NM_001258390.1; = p.Y284C on NM_178834.5) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65105606; called by muse, mutect2, varscan2
- LCMT1 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66727498; called by muse, mutect2, varscan2
- LCN6 | c.413-2A>G p.X138_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100366318; called by mutect2, varscan2
- LCP2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as rs765182237, COSV50468372; called by muse, mutect2, varscan2
- LCT | c.4478A>G p.H1493R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51558024; called by muse, mutect2
- LCT | c.3224G>A p.G1075D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV51558040; called by muse, mutect2, varscan2
- LDB3 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.059); catalogued as rs770678454, COSV53950206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LEF1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.491); catalogued as COSV54473679; called by muse, mutect2, varscan2
- LGI2 | c.1166T>C p.L389P | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66124187; called by muse, mutect2
- LHFPL1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.923); catalogued as rs755985950, COSV64334231; called by muse, mutect2, varscan2
- LIN54 | c.961T>C p.S321P | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV61202992; called by muse, mutect2
- LMAN1L | c.1469G>A p.S490N | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV59000857; called by muse, mutect2, varscan2
- LNPEP | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs1422503399, COSV51481607; called by muse, mutect2, varscan2
- LPCAT4 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.069); catalogued as COSV59219195; called by muse, mutect2, varscan2
- LRP1 | c.4268G>A p.R1423H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777476570, COSV54515929; called by muse, mutect2, varscan2
- LRP12 | c.1124G>T p.C375F | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52634962; called by muse, mutect2, varscan2
- LRP12 | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV52634978; called by muse, mutect2, varscan2
- LRP8 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767691715, COSV60098553; called by muse, mutect2, varscan2
- LRRC52 | c.252T>A p.C84* | Nonsense Mutation (SNP) | VAF 81/330 reads (25%) | catalogued as COSV54233905, COSV99673894; called by muse, varscan2
- LRRK2 | c.3632T>C p.L1211P | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54172179; called by muse, mutect2, varscan2
- LRRN3 | c.904A>G p.S302G | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57821896; called by muse, mutect2, varscan2
- LRRN3 | c.1220T>A p.V407D | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV57824229; called by muse, mutect2, varscan2
- LRTM1 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV55570703; called by muse, mutect2, varscan2
- LTBP2 | c.1535del p.P512Rfs*45 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as COSV56210216; called by mutect2, pindel, varscan2
- MAK16 | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62453736; called by muse, mutect2, varscan2
- MAN2B2 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs768266831, COSV53457141; called by muse, mutect2, varscan2
- MAP2K7 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67608687; called by muse, mutect2, varscan2
- MAP3K12 | c.2026G>T p.G676W | Missense Mutation (SNP) | VAF 56/423 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV57236626; called by muse, mutect2, varscan2
- MAP7D3 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV60171031; called by muse, mutect2, varscan2
- MAPK15 | c.1538del p.G513Vfs*? | Frame Shift Del (DEL) | VAF 20/154 reads (13%) | catalogued as rs782558070; called by mutect2, pindel, varscan2
- MBD2 | c.471del p.G158Dfs*7 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs755716804, COSV56502366; called by mutect2, pindel, varscan2
- MBD3 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as rs757544695, COSV50085791; called by muse, mutect2, varscan2
- MCM4 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.142); catalogued as COSV50633310; called by muse, mutect2, varscan2
- MEAF6 | c.534-1G>A p.X178_splice (on ENST00000296214 / NM_001270875.3; = p.X188_splice on NM_022756.6) | Splice Site (SNP) | VAF 26/128 reads (20%) | catalogued as rs773417627, COSV56164727; called by muse, mutect2, varscan2
- MED12L | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1235293277, COSV56398892; called by muse, mutect2
- MFN2 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs1226075443, COSV52420297; called by muse, mutect2, varscan2
- MFSD12 | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as COSV61536856; called by muse, mutect2, varscan2
- MGAT5 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | catalogued as COSV56099538; called by muse, mutect2, varscan2
- MGST1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs746981523, COSV50567164; called by muse, mutect2, varscan2
- MICAL3 | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.984); catalogued as rs1046329010, COSV71588909; called by muse, mutect2, varscan2
- MIDEAS | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV54099359; called by muse, mutect2, varscan2
- MIER2 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs150878648; called by muse, mutect2, varscan2
- MINDY2 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1169761376, COSV57508894; called by muse, mutect2, varscan2
- MLH3 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs770819541, COSV53154757; called by muse, mutect2, varscan2
- MLLT6 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1269191444; called by muse, varscan2
- MLXIPL | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57670616; called by muse, mutect2
- MOB1B | c.567del p.F189Lfs*19 | Frame Shift Del (DEL) | VAF 28/123 reads (23%) | catalogued as rs778232663; called by mutect2, varscan2
- MOB2 | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57317954, COSV57319628; called by muse, mutect2, varscan2
- MPPED1 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201093627, COSV68839353; called by muse, mutect2, varscan2
- MRGPRX2 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV61675003; called by muse, mutect2, varscan2
- MRGPRX3 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs781690794, COSV66934882; called by muse, mutect2, varscan2
- MRPS24 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as rs747409691, COSV58182401; called by muse, mutect2, varscan2
- MSH6 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs587780669, COSV52288816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTBP | c.484+2T>C p.X162_splice | Splice Site (SNP) | VAF 10/59 reads (17%) | catalogued as COSV59966704; called by muse, mutect2, varscan2
- MTMR11 | c.770C>T p.P257L (on ENST00000439741 / NM_001145862.2; = p.P185L on NM_181873.3) | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782450905, COSV63808856; called by muse, mutect2, varscan2
- MTMR6 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1246015107, COSV67809912; called by muse, mutect2, varscan2
- MTRR | c.405del p.K136Rfs*2 (on ENST00000264668; = p.K109Rfs*2 on NM_002454.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 51/307 reads (17%) | catalogued as rs1189298981; called by mutect2, pindel, varscan2
- MUC16 | c.20048C>T p.T6683I | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV67496283; called by muse, mutect2, varscan2
- MUC5B | c.10354G>A p.A3452T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV71591787; called by muse, mutect2
- MXD1 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 46/186 reads (25%) | catalogued as COSV52480986; called by muse, mutect2, varscan2
- MYH10 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV52612043; called by muse, mutect2, varscan2
- MYLK | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 223/574 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV60623442; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 24/131 reads (18%) | catalogued as rs760302326; called by mutect2, varscan2
- MYOD1 | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.247); catalogued as COSV51455818; called by muse, mutect2, varscan2
- MYOM2 | c.2127C>A p.T709= | Splice Region (SNP) | VAF 48/261 reads (18%) | catalogued as COSV50780187; called by muse, mutect2, varscan2
- N4BP2 | c.1589C>A p.S530Y | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54707277; called by muse, mutect2, varscan2
- NCAPD3 | c.4468C>T p.R1490* | Nonsense Mutation (SNP) | VAF 12/296 reads (4%) | catalogued as rs1228289225, COSV54452944; called by muse, mutect2
- NCDN | c.1876T>C p.Y626H | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61937334; called by muse, mutect2
- NCK2 | c.432C>G p.C144W | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51896664; called by muse, mutect2, varscan2
- NCKAP1L | c.2725A>G p.T909A | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV53212720; called by muse, mutect2, varscan2
- NCOR1 | c.7192C>T p.P2398S | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1401314085, COSV51997749; called by muse, mutect2, varscan2
- NDUFAF6 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs372973430; called by muse, mutect2, varscan2
- NDUFS4 | c.422del p.N141Mfs*48 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | catalogued as rs1323319971; called by mutect2, pindel
- NEB | c.7742C>T p.A2581V | Missense Mutation (SNP) | VAF 106/545 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51462432; called by muse, mutect2, varscan2
- NEBL | c.903C>T p.G301= | Splice Region (SNP) | VAF 27/73 reads (37%) | catalogued as rs200799762, COSV65805302; called by muse, mutect2, varscan2
- NECAP2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1474257576, COSV61434475; called by muse, mutect2, varscan2
- NEK10 | c.3289T>C p.F1097L | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV55365880; called by muse, mutect2
- NFATC1 | c.1349C>G p.A450G | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV53695820, COSV53710046; called by muse, mutect2, varscan2
- NFATC4 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV51612376; called by muse, mutect2
- NHLH2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs1201976289, COSV57202855, COSV57203025; called by muse, mutect2, varscan2
- NIBAN1 | c.2218G>A p.V740I | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs140276880; called by muse, mutect2, varscan2
- NKX2-3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs777007213, COSV60729344; called by mutect2, varscan2
- NLGN3 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.305); catalogued as rs768698460, COSV62444562; called by muse, mutect2, varscan2
- NLGN4X | c.1208T>C p.V403A | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99319468; called by muse, mutect2, varscan2
- NLRP4 | c.2321T>C p.L774P | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56724077; called by muse, mutect2, varscan2
- NME7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs563279223, COSV63165095; called by muse, mutect2, varscan2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as rs754069719; called by mutect2, pindel, varscan2
- NOD1 | c.1519G>A p.G507R | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as rs566081250, COSV56114953; called by muse, varscan2
- NOD2 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs148516118, CM030413, COSV56055090; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs759637346; called by mutect2, varscan2
- NOS1 | c.4271G>A p.S1424N | Missense Mutation (SNP) | VAF 42/477 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV57622461; called by muse, mutect2
- NOS1 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV57622470; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NOTCH2 | c.5351T>A p.I1784N | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.235); catalogued as COSV56707236; called by muse, mutect2, varscan2
- NOTCH3 | c.629del p.G210Afs*26 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as COSV54629154; called by mutect2, pindel, varscan2
- NPHP4 | c.3268G>A p.A1090T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs573269001, COSV65398242; called by muse, mutect2, varscan2
- NQO2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV57643702; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs774343392; called by mutect2, varscan2
- NR2F6 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs372090950; called by muse, mutect2, varscan2
- NRAP | c.2423T>C p.L808P (on ENST00000359988 / NM_001322945.2; = p.L773P on NM_006175.4) | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV100748690, COSV63494193; called by muse, mutect2, varscan2
- NRROS | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs1459933887, COSV60747901; called by muse, mutect2, varscan2
- NRXN2 | c.2666G>A p.G889D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV55464024; called by muse, mutect2, varscan2
- NRXN3 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV55366600; called by muse, mutect2, varscan2
- NSG1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.994); catalogued as rs199877139, COSV67575404, COSV67575940; called by muse, mutect2, varscan2
- NT5M | c.622del p.R208Afs*34 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs754390000; called by mutect2, pindel, varscan2
- NUP160 | c.2410T>A p.L804I | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.299); catalogued as COSV65856225; called by muse, mutect2, varscan2
- NUP205 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200662632; called by muse, mutect2, varscan2
- NUP210 | c.4606T>C p.Y1536H | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV54414589; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs760869296; called by mutect2, varscan2
- OBSCN | c.17915G>T p.W5972L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV52809295, COSV52833258; called by muse, mutect2, varscan2
- ODF2L | c.1221del p.K407Nfs*22 (on ENST00000317336; = p.K378Nfs*22 on NM_020729.3) | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs761049141, COSV54018443; called by mutect2, varscan2
- OPCML | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as rs1277887639, COSV59401918, COSV59452339; called by muse, mutect2, varscan2
- OPN3 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs376508772, COSV59367597; called by muse, mutect2, varscan2
- OR1S1 | c.213del p.M72Cfs*25 | Frame Shift Del (DEL) | VAF 39/337 reads (12%) | catalogued as rs761074067, COSV58706814; called by mutect2, pindel, varscan2
- OR2AK2 | c.474A>G p.I158M | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV63561550; called by muse, mutect2
- OR2C1 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 43/113 reads (38%) | catalogued as COSV100514811; called by muse, mutect2, varscan2
- OR2D2 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV55058361; called by muse, mutect2, varscan2
- OR4C13 | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs1223336473, COSV73648949; called by muse, mutect2, varscan2
- OR4K15 | c.781C>T p.R261C (on ENST00000305051; = p.R237C on NM_001005486.1) | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs755366458, COSV59300834, COSV59301626, COSV59303559; called by muse, mutect2, varscan2
- OR4X1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs570472966, COSV60724042; called by muse, mutect2, varscan2
- OR52E4 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV57626366; called by muse, mutect2, varscan2
- OR52E4 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs768164155, COSV57623964, COSV57624022; called by muse, mutect2, varscan2
- OR5AP2 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756963104, COSV57257858; called by muse, mutect2, varscan2
- OR6C65 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.036); catalogued as COSV65569541; called by muse, mutect2, varscan2
- OSBP2 | c.1887dup p.S630Lfs*79 | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | catalogued as rs772802379; called by mutect2, varscan2
- OTUD7B | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753757221, COSV64917881; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as CD124838, COSV100258088; called by mutect2, pindel, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs763394045; called by mutect2, varscan2
- PAK2 | c.774-1G>A p.X258_splice | Splice Site (SNP) | VAF 16/144 reads (11%) | catalogued as COSV59085698; called by muse, mutect2, varscan2
- PALM | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs763907757, COSV52770892, COSV52771013; called by muse, mutect2
- PANX2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1447920199, COSV50317292; called by muse, mutect2, varscan2
- PARD3B | c.1378del p.E460Rfs*19 | Frame Shift Del (DEL) | VAF 33/160 reads (21%) | catalogued as rs1296928742; called by mutect2, pindel, varscan2
- PARP8 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55867287; called by muse, mutect2, varscan2
- PBLD | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs750680281, COSV53266398; called by muse, mutect2, varscan2
- PBRM1 | c.4551del p.P1518Lfs*21 (on ENST00000296302 / NM_001366071.2; = p.P1411Lfs*21 on NM_018313.5) | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as rs1559827261; called by mutect2, pindel, varscan2
- PCARE | c.2966del p.P989Lfs*46 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | catalogued as rs770881706; called by mutect2, pindel, varscan2
- PCDH15 | c.5153C>T p.P1718L | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV57400182; called by muse, mutect2, varscan2
- PCDH8 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.083); catalogued as COSV58815177; called by muse, mutect2, varscan2
- PCDH9 | c.3037-1G>A p.X1013_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV60592968; called by muse, mutect2
- PCDHA2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65371421; called by muse, mutect2, varscan2
- PCDHA5 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782012519, COSV65356633, COSV65358305; called by muse, mutect2, varscan2
- PCDHAC2 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.508); catalogued as COSV53858240; called by muse, mutect2, varscan2
- PCDHB1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV60633481; called by muse, mutect2, varscan2
- PCDHB12 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV53396851; called by muse, mutect2, varscan2
- PCDHB5 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.975); catalogued as rs782121687, COSV50673381; called by muse, mutect2, varscan2
- PCDHB8 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 25/434 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs1389259004, COSV50819819, COSV99177366; called by muse, mutect2
- PCDHB8 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 47/755 reads (6%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.05); catalogued as rs782643110, COSV50762098; called by muse, mutect2
- PCDHGA1 | c.2341A>G p.S781G | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); catalogued as rs1384789799, COSV65299982; called by muse, mutect2, varscan2
- PCDHGA10 | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV54039771; called by muse, mutect2, varscan2
- PCDHGB1 | c.2105C>T p.A702V | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV54039750; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNT | c.250G>T p.G84W | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52451927; called by muse, mutect2, varscan2
- PCTP | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs371967661; called by muse, mutect2, varscan2
- PDZD2 | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372658069; called by muse, mutect2, varscan2
- PEF1 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV65484383; called by muse, mutect2
- PELI3 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775263947, COSV57857871; called by muse, mutect2, varscan2
- PEPD | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs533996123, COSV54890142; called by muse, mutect2, varscan2
- PEX1 | c.2717A>G p.K906R | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV50421103; called by muse, varscan2
- PEX16 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs774218187, COSV53804403; called by muse, mutect2, varscan2
- PFDN5 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54477198; called by muse, mutect2, varscan2
- PGS1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV99427931; called by muse, mutect2, varscan2
- PHF23 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs533278658, COSV50039892; called by muse, mutect2, varscan2
- PHF23 | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50039894; called by muse, mutect2, varscan2
- PHKA1 | c.3188C>T p.A1063V | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV59812161; called by muse, mutect2, varscan2
- PHLDB2 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1027768536, COSV67316430; called by muse, mutect2, varscan2
- PIK3R6 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV61004479; called by muse, mutect2, varscan2
- PJA1 | c.1698T>A p.N566K (on ENST00000361478 / NM_145119.4; = p.N378K on NM_022368.5) | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV64053816; called by muse, mutect2, varscan2
- PKD1 | c.6608G>A p.R2203H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs765511448, COSV51927630, COSV99236957; called by muse, varscan2
- PKD1 | c.2866G>A p.V956M | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs748744124, COSV51920636; called by muse, mutect2, varscan2
- PKHD1 | c.4601G>A p.S1534N | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100584911, COSV61895893; called by muse, mutect2, varscan2
- PKLR | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV61362605; called by muse, mutect2, varscan2
- PLAG1 | c.551del p.K184Sfs*45 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | catalogued as rs141930943; called by mutect2, pindel, varscan2
- PLCE1 | c.3455T>A p.L1152* | Nonsense Mutation (SNP) | VAF 73/377 reads (19%) | catalogued as COSV53373625; called by muse, mutect2, varscan2
- PLEK2 | c.45C>T p.G15= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as COSV53607003; called by muse, mutect2, varscan2
- PLEKHA1 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV64570471; called by muse, mutect2, varscan2
- PLEKHA6 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775381290, COSV55340642; called by muse, varscan2
- PLEKHG4 | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as rs752381179, COSV58574446; called by muse, mutect2, varscan2
- PLXNA4 | c.1286G>T p.R429M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV58135357; called by muse, mutect2, varscan2
- PLXNB1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as rs764518586, COSV99602074; called by muse, mutect2, varscan2
- PNPLA6 | c.3812G>A p.R1271Q (on ENST00000414982 / NM_001166111.2; = p.R1223Q on NM_006702.5) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.163); catalogued as rs1354670102, COSV55385807; called by muse, mutect2, varscan2
- PODN | c.1820C>T p.A607V (on ENST00000395871; = p.A559V on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.458); catalogued as COSV57017595; called by muse, mutect2, varscan2
- POFUT2 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775138574, COSV57961328; called by muse, mutect2, varscan2
- POLA1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs748968830, COSV66883451; called by mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLG2 | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.821); catalogued as COSV73377016; called by muse, mutect2, varscan2
- POLR2B | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.739); catalogued as COSV58902997; called by muse, mutect2, varscan2
- POLR2B | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.042); catalogued as COSV58900132, COSV58903003; called by muse, mutect2, varscan2
- POM121 | c.2057C>T p.T686M (on ENST00000434423; = p.T421M on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs551810669, COSV57524328; called by mutect2, varscan2
- POM121L12 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV68694520; called by muse, mutect2, varscan2
- PPFIA2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs866062171, COSV61056569; called by muse, mutect2
- PPFIA4 | c.2918G>A p.R973H (on ENST00000447715; = p.R974H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1410964055, COSV55315741; called by muse, mutect2, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs775130624; called by mutect2, pindel, varscan2
- PPIL1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV65472727; called by muse, mutect2, varscan2
- PPP1R15A | c.1199A>G p.E400G | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52340358; called by muse, mutect2, varscan2
- PRDM10 | c.2452A>G p.M818V | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1256596146, COSV58803898, COSV58805531; called by muse, mutect2, varscan2
- PRDM2 | c.2621C>T p.T874M | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs145695645; called by muse, mutect2, varscan2
- PREX2 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1214968217, COSV55757091; called by muse, mutect2
- PRG4 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV63356544; called by muse, mutect2, varscan2
- PRICKLE1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs372213429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKAB1 | c.80del p.G27Afs*11 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as COSV57555398; called by mutect2, pindel, varscan2
- PRKCD | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57851859; called by muse, mutect2, varscan2
- PRKG1 | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64777788, COSV64778663; called by muse, mutect2, varscan2
- PRKG2 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV52320652, COSV52332497; called by muse, mutect2, varscan2
- PRKX | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 37/138 reads (27%) | catalogued as COSV53327009; called by muse, mutect2, varscan2
- PRORP | c.257del p.L86* | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs760446387; called by mutect2, varscan2
- PROSER2 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs758163603, COSV53207695; called by muse, mutect2, varscan2
- PRPF8 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59268176; called by muse, mutect2, varscan2
- PRRC2C | c.4532G>A p.R1511Q (on ENST00000367742; = p.R1509Q on NM_015172.4) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs951759557, COSV58909213, COSV58913976; called by muse, mutect2, varscan2
- PSD2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as rs1166700304, COSV51199827; called by muse, mutect2, varscan2
- PSD4 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs754405162, COSV55528924; called by muse, mutect2, varscan2
- PSKH2 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV52612853; called by muse, mutect2, varscan2
- PSRC1 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64021764; called by muse, mutect2, varscan2
- PSTPIP2 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs759856340, COSV68958047; called by muse, mutect2, varscan2
- PTGES2 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779731411, COSV52969481; called by muse, mutect2, varscan2
- PTPA | c.718G>A p.G240S (on ENST00000337738 / NM_178001.2; = p.G205S on NM_021131.5) | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs954227908, COSV61234514; called by muse, mutect2, varscan2
- PTPN23 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs750641394, COSV55548625; called by muse, mutect2, varscan2
- PTPRN2 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs199560003, COSV67060709; called by muse, mutect2, varscan2
- PTPRT | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1293790183, COSV100624601, COSV62024441; called by muse, mutect2
- PTX3 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.265); catalogued as COSV55821673; called by muse, mutect2, varscan2
- PUS7L | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as COSV61263036; called by muse, mutect2
- RAB11FIP1 | c.110del p.G37Afs*8 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as rs760708200; called by mutect2, pindel, varscan2
- RAB39A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV100269039; called by muse, mutect2, varscan2
- RAB3C | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.95); catalogued as COSV51432891; called by muse, mutect2, varscan2
- RAB3IP | c.949T>G p.L317V (on ENST00000550536 / NM_175623.4; = p.L301V on NM_022456.5) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV56086869; called by muse, mutect2, varscan2
- RADIL | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV68203888; called by muse, mutect2, varscan2
- RAI1 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs754646763, COSV55394805, COSV55399577; called by muse, mutect2, varscan2
- RALGDS | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748828691, COSV64427016; called by muse, mutect2, varscan2
- RAP1A | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750039775, COSV62728373; called by muse, mutect2, varscan2
- RAPGEF1 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs764842655, COSV64702527; called by muse, mutect2, varscan2
- RASGEF1A | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as rs569429774, COSV65666872; called by muse, mutect2, varscan2
- RASSF4 | c.902T>C p.M301T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.062); catalogued as COSV58489080; called by muse, mutect2, varscan2
- RB1 | c.1848del p.G617Vfs*6 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | catalogued as CM092255, COSV57309246; called by mutect2, pindel, varscan2
- RBM14 | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs1211559235, COSV59560888; called by muse, mutect2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs751690893; called by mutect2, varscan2
- RBM46 | c.1219T>A p.W407R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55982177; called by muse, mutect2, varscan2
- RBM6 | c.293dup p.D99Rfs*6 | Frame Shift Ins (INS) | VAF 54/180 reads (30%) | catalogued as rs764709206; called by mutect2, varscan2
- RBM6 | c.2944C>T p.Q982* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV56488408; called by muse, mutect2, varscan2
- RBMS1 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as COSV62357455; called by muse, mutect2, varscan2
- RDH12 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778481181, COSV50823291; called by muse, mutect2, varscan2
- REG1A | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs777579151, COSV52071733, COSV52072168; called by muse, mutect2, varscan2
- RELCH | c.2701G>A p.V901I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV56892845; called by muse, mutect2
- RFC1 | c.1884C>T p.H628= | Splice Region (SNP) | VAF 48/236 reads (20%) | catalogued as rs201668482; called by muse, mutect2, varscan2
- RHOBTB2 | c.1594C>G p.P532A | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV52573487; called by muse, mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 22/116 reads (19%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RHPN1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs764387997, COSV56647721; called by muse, mutect2
- RIMS2 | c.2912G>A p.R971H (on ENST00000666250 / NM_001348490.2; = p.R779H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs750833472, COSV51668611, COSV99169380; called by muse, mutect2, varscan2
- RIN1 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV60929044; called by muse, mutect2, varscan2
- RING1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 48/336 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as COSV63002338, COSV63002992; called by muse, mutect2
- RND3 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs749653637, COSV55726118; called by muse, mutect2, varscan2
- RNF123 | c.1337_1339del p.E446del | In Frame Del (DEL) | VAF 17/144 reads (12%) | catalogued as rs777029614; called by pindel, varscan2
- RNF20 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66662476; called by muse, mutect2, varscan2
- RNF213 | c.3024G>T p.Q1008H | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100172861; called by muse, mutect2, varscan2
- RNF213 | c.11587G>A p.A3863T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs577982374, COSV60409697; called by muse, mutect2, varscan2
- RNF40 | c.2297A>G p.E766G | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61216858; called by muse, mutect2, varscan2
- RNF43 | c.2102G>A p.C701Y | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV68460424; called by muse, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 22/178 reads (12%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 34/183 reads (19%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- RNPEPL1 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs193086300; called by muse, mutect2, varscan2
- RP1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV55119207; called by muse, mutect2, varscan2
- RP1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs747000732, COSV55119519; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPN2 | c.1096A>G p.R366G | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as rs1245812789, COSV52905453, COSV52909269; called by muse, mutect2, varscan2
- RPTOR | c.2444T>C p.L815P | Missense Mutation (SNP) | VAF 86/406 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60818850; called by muse, mutect2, varscan2
- RRH | c.324del p.F108Lfs*18 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | catalogued as rs751964437; called by mutect2, varscan2
- RRP12 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1342540709, COSV59671726; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 19/111 reads (17%) | catalogued as rs759252078; called by mutect2, varscan2
- RTN4RL2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs746854837, COSV58653151; called by muse, mutect2, varscan2
- RYR2 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 72/392 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs955065308, CM097929, COSV63716501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.6266C>T p.S2089L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.089); catalogued as rs370095300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD15 | c.1876G>A p.G626S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs267604065, COSV53630632; called by muse, mutect2, varscan2
- SAMD9L | c.4224del p.K1408Nfs*10 | Frame Shift Del (DEL) | VAF 116/412 reads (28%) | catalogued as rs759143613, COSV59085428; called by mutect2, pindel, varscan2
- SAP130 | c.2917C>T p.Q973* | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | catalogued as COSV52103328; called by muse, mutect2, varscan2
- SARS1 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs753604964, COSV52322359; called by muse, mutect2, varscan2
- SASS6 | c.1624C>A p.P542T | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54926197, COSV54930592; called by muse, mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs763290832; called by mutect2, varscan2
- SAV1 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as rs778540402, COSV61204833; called by muse, mutect2, varscan2
- SCAF1 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as rs767108871, COSV55868075; called by muse, mutect2, varscan2
- SCAI | c.1613G>A p.R538H (on ENST00000336505 / NM_001144877.3; = p.R561H on NM_173690.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57176282; called by muse, mutect2, varscan2
- SCLT1 | c.1620dup p.A541Sfs*11 | Frame Shift Ins (INS) | VAF 22/119 reads (18%) | catalogued as rs760494753; called by mutect2, varscan2
- SCN10A | c.3425G>A p.R1142H | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200584416, COSV71860372; called by muse, mutect2, varscan2
- SCUBE2 | c.2616del p.K873Sfs*5 (on ENST00000649792 / NM_001367977.2; = p.K816Sfs*5 on NM_020974.3) | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | catalogued as rs753114269; called by mutect2, pindel, varscan2
- SEC14L4 | c.644G>T p.R215M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99742533; called by muse, mutect2
- SEC23IP | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV64833236; called by muse, mutect2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEL1L | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs141918133; called by muse, mutect2, varscan2
- SEL1L2 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377623069, COSV53155199, COSV53158702; called by muse, mutect2, varscan2
- SEMA6A | c.1520T>C p.V507A | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV56715225; called by muse, mutect2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINA6 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.071); catalogued as rs202078426, COSV58583804; called by muse, mutect2, varscan2
- SETBP1 | c.4762C>T p.R1588* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as CM1212389, COSV56328307, COSV56337748; called by muse, mutect2, varscan2
- SETX | c.5454A>G p.I1818M | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV56395266; called by muse, mutect2, varscan2
- SGO1 | c.1084_1086del p.N362del | In Frame Del (DEL) | VAF 21/144 reads (15%) | catalogued as rs758708257; called by pindel, varscan2
- SH2D2A | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV63885263, COSV63885558; called by muse, mutect2, varscan2
- SH3PXD2A | c.3328T>C p.Y1110H (on ENST00000369774 / NM_001365079.1; = p.Y1082H on NM_014631.2) | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60120912; called by muse, mutect2, varscan2
- SHANK2 | c.3560C>T p.A1187V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs1259438131, COSV53620323; called by muse, mutect2
- SHD | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV73378793; called by muse, mutect2, varscan2
- SIN3B | c.2079G>C p.Q693H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56136699; called by muse, mutect2, varscan2
- SINHCAF | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.389); catalogued as COSV100530447; called by muse, mutect2, varscan2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | catalogued as rs771414532; called by mutect2, varscan2
- SIPA1L3 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV55924916; called by muse, mutect2, varscan2
- SKIV2L | c.3251T>C p.M1084T | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs766854756, COSV61715189; called by muse, mutect2, varscan2
- SKOR1 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58250236; called by muse, mutect2, varscan2
- SLC11A1 | c.1419G>A p.M473I | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV51919801; called by muse, mutect2, varscan2
- SLC15A3 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV50024480; called by muse, mutect2, varscan2
- SLC1A7 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146594134; called by muse, mutect2, varscan2
- SLC22A2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.7); catalogued as rs771411024, COSV65267513; called by muse, mutect2, varscan2
- SLC25A35 | c.729+1G>A p.X243_splice | Splice Site (SNP) | VAF 43/163 reads (26%) | catalogued as COSV56840324; called by muse, mutect2, varscan2
753 further variants in this file (391 protein-altering or splice-affecting, 339 silent, 23 other) are not listed here.
